MMRF case MMRF_2413 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/46ee3fe1-0bf0-49cd-af4a-e0e888b92965

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.4 years (22,428 days); ISS stage: III; Days to last known disease status: 714 days (2.0 years); Days to last follow up: 714 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 48 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 2): M Protein 8.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 2 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 8.8 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 4.46 mmol/L; Leukocytes 3.71 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 28 g/L; Total Protein 11.8 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 74 (ECOG 3): M Protein 1.97 g/dL; Lactate Dehydrogenase 5.57 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.65 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 158 (ECOG 2): M Protein 0 g/dL; Lactate Dehydrogenase 8.3 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 9.58 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 89.3 µmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 12.8 mmol/L.
- Day 272: M Protein 0 g/dL; Lactate Dehydrogenase 6.75 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.89 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 89.3 µmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 7.48 mmol/L.
- Day 371: Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 5 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 7.98 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 91.1 µmol/L; Calcium 2.13 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 27.6 mmol/L.
- Day 455: Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Lactate Dehydrogenase 7.18 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.83 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 98.1 µmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 13.4 mmol/L.
- Day 511: Lactate Dehydrogenase 6.03 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.39 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 98.1 µmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 12.2 mmol/L.
- Day 595: M Protein 2.07 g/dL; Lactate Dehydrogenase 6.07 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.95 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 90.2 µmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 12.2 mmol/L.
- Day 714: M Protein 5.39 g/dL; Lactate Dehydrogenase 5.18 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.35 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 99.9 µmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 11.7 mmol/L.

Other clinical attributes
- Day -9: Weight: 98 kg; Height: 183 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples)
- Sample MMRF_2413_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2413_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
